Somatic mutation profile of tumor specimen TCGA-F4-6855-01A (aliquot TCGA-F4-6855-01A-11D-1924-10) from TCGA case TCGA-F4-6855, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.9 years (25,890 days).
Specimen TCGA-F4-6855-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f16b20d9-b0ac-4932-b5b6-94e2d24515d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F4-6855-10A (Blood Derived Normal), aliquot TCGA-F4-6855-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8ca8800-0da4-49fb-936d-53c3a3ae958f

The open-access MAF lists 112 somatic variants for this specimen: 83 protein-altering or splice-affecting, 28 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 28, Nonsense Mutation 10, Splice Site 7, Splice Region 2, Frame Shift Del 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2805C>A p.Y935* | Nonsense Mutation (SNP) | VAF 17/81 reads (21%) | hotspot (GDC flag); catalogued as rs137854575, CD041148, CM920044, CM970086, COSV57324059, COSV57328770; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4285C>T p.Q1429* | Nonsense Mutation (SNP) | VAF 55/108 reads (51%) | hotspot (GDC flag); catalogued as rs74535574, HM050024, COSV57322632, COSV57333893; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAH11 | c.3544C>T p.R1182* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | catalogued as rs374107286; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EVC2 | c.2476C>T p.R826* | Nonsense Mutation (SNP) | VAF 17/67 reads (25%) | catalogued as rs548681312, CM098967, COSV60388652; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 69/144 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 31/69 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.533C>A p.S178* | Nonsense Mutation (SNP) | VAF 19/60 reads (32%) | hotspot (GDC flag); catalogued as CM994756, COSV61686156, COSV61688610, COSV61689431; called by muse, mutect2, varscan2
- ADAM7 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs746112199, COSV51537523, COSV51541741; called by muse, mutect2, varscan2
- ADAMTS13 | c.2815C>T p.P939S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63022503; called by muse, mutect2, varscan2
- APOB | c.3916T>C p.S1306P | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99266970; called by muse, mutect2, varscan2
- ARHGAP22 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as rs534705917, COSV50933246; called by muse, mutect2, varscan2
- ATP8A2 | c.2679G>A p.E893= | Splice Region (SNP) | VAF 17/114 reads (15%) | catalogued as rs149637047, COSV54968106; called by muse, mutect2, varscan2
- BIN2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758843494, COSV99909600; called by muse, mutect2, varscan2
- C6orf118 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs545305011, COSV100025344, COSV57814424; called by muse, mutect2, varscan2
- CASD1 | c.592T>G p.L198V | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV51974510; called by muse, mutect2, varscan2
- CCDC117 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 124/272 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV50771125; called by muse, mutect2, varscan2
- CCDC34 | c.731dup p.N244Kfs*3 | Frame Shift Ins (INS) | VAF 38/185 reads (21%) | catalogued as rs773019149; called by mutect2, varscan2
- CD300LG | c.778T>C p.S260P | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV99517557; called by muse, mutect2, varscan2
- CD99L2 | c.130+1G>A p.X44_splice | Splice Site (SNP) | VAF 10/75 reads (13%) | catalogued as rs782628647, COSV57988184; called by muse, mutect2, varscan2
- CDH9 | c.1409G>T p.S470I | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV99150512; called by muse, mutect2, varscan2
- CHRNB2 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.301); catalogued as rs760653937, COSV63807926; called by muse, mutect2, varscan2
- COL5A1 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as rs767752804, COSV65668467; called by muse, mutect2, varscan2
- COL6A3 | c.3084G>T p.K1028N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99800164; called by muse, mutect2
- CROCC | c.3202G>A p.E1068K | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65014000; called by muse, mutect2, varscan2
- CRYBG2 | c.4241G>T p.G1414V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57488353; called by muse, mutect2, varscan2
- CTNNA3 | c.2398G>T p.A800S | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as COSV65521126; called by muse, mutect2, varscan2
- CYFIP2 | c.2532C>G p.S844R (on ENST00000616178 / NM_001291722.2; = p.S819R on NM_014376.4) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.291); catalogued as COSV56637487; called by muse, mutect2, varscan2
- DCDC1 | c.5114C>A p.P1705Q (on ENST00000597505 / NM_001367979.1; = p.P812Q on NM_020869.3) | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV58001802; called by muse, mutect2, varscan2
- DDI1 | c.595C>A p.R199S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV100160205, COSV56371392; called by muse, mutect2, varscan2
- DENND4A | c.5042G>A p.R1681H | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs1438473936, COSV71266631; called by muse, mutect2, varscan2
- DHX37 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58132235; called by muse, mutect2, varscan2
- DTWD2 | c.597+1G>T p.X199_splice | Splice Site (SNP) | VAF 15/54 reads (28%) | catalogued as COSV58368264; called by muse, mutect2, varscan2
- FLNB | c.3488C>T p.P1163L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); catalogued as rs1163015683, COSV99914129; called by muse, mutect2, varscan2
- GAA | c.2384A>G p.E795G | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV56410459, COSV56411663; called by muse, mutect2, varscan2
- GPR52 | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 259/430 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as COSV52314678; called by muse, mutect2, varscan2
- H1-1 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.835); catalogued as rs1355502406, COSV55120207; called by muse, mutect2, varscan2
- HMCN1 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 13/135 reads (10%) | catalogued as rs776450081, COSV54876415; called by muse, mutect2, varscan2
- HSF1 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68821499, COSV68822034; called by muse, mutect2, varscan2
- IGF2BP1 | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51734216, COSV99288400; called by muse, mutect2, varscan2
- IL11RA | c.477G>A p.Q159= | Splice Region (SNP) | VAF 10/48 reads (21%) | catalogued as COSV52405396; called by muse, mutect2, varscan2
- IL1RAPL1 | c.951C>G p.I317M | Missense Mutation (SNP) | VAF 91/430 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.776); catalogued as COSV100151302, COSV56285555; called by muse, mutect2, varscan2
- INSL6 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1322949204, CM115319, COSV67562842; called by muse, mutect2, varscan2
- ITGA8 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as rs748005596, COSV65229891; called by muse, mutect2, varscan2
- KRT12 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52431953; called by muse, mutect2, varscan2
- LMX1A | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 19/90 reads (21%) | catalogued as rs776905403, COSV54225521; called by muse, mutect2, varscan2
- MCC | c.2141G>T p.C714F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV56733376; called by muse, mutect2, varscan2
- MFSD1 | c.1195C>T p.L399F | Missense Mutation (SNP) | VAF 90/392 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV99963992; called by muse, mutect2, varscan2
- MUC16 | c.6352G>A p.A2118T | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs749152513, COSV67455691; called by muse, mutect2, varscan2
- MYOM2 | c.793+1G>A p.X265_splice | Splice Site (SNP) | VAF 89/410 reads (22%) | catalogued as COSV50747581; called by muse, mutect2, varscan2
- NAV1 | c.4277G>A p.R1426K | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as COSV55222905; called by muse, mutect2, varscan2
- NAV3 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 21/90 reads (23%) | catalogued as rs1480204948, COSV57080262, COSV57106346, COSV99887406; called by muse, mutect2, varscan2
- NOD2 | c.2368C>T p.R790W | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs62029861, CM065048, COSV56053574; called by muse, mutect2, varscan2
- NUP205 | c.4231+8dup p.X1411_splice | Splice Site (INS) | VAF 23/60 reads (38%) | catalogued as rs748861286; called by mutect2, varscan2
- OCM2 | c.62-1G>C p.X21_splice | Splice Site (SNP) | VAF 33/97 reads (34%) | catalogued as COSV57535770; called by muse, mutect2, varscan2
- OR2M3 | c.845C>G p.T282S | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV71759214; called by muse, mutect2, varscan2
- PAQR7 | c.433G>T p.G145W | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65352044; called by muse, mutect2, varscan2
- PLCH2 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as rs1376074481, COSV53947423; called by muse, mutect2, varscan2
- POLQ | c.6901G>T p.E2301* | Nonsense Mutation (SNP) | VAF 28/63 reads (44%) | catalogued as COSV99952621; called by muse, mutect2, varscan2
- PRLHR | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.359); catalogued as rs756981778, COSV53304687; called by muse, mutect2, varscan2
- RASGRF1 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV67250813; called by muse, mutect2, varscan2
- RIMS2 | c.2261T>A p.L754H (on ENST00000666250 / NM_001348490.2; = p.L562H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99179739; called by muse, mutect2, varscan2
- SAP30 | c.376A>G p.R126G | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99633192; called by muse, varscan2
- SDK1 | c.2458C>T p.R820W | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs759323106, COSV67379581; called by mutect2, varscan2
- SLC25A19 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.362); catalogued as rs200977389, COSV55469406, COSV99823684; called by muse, mutect2, varscan2
- SLITRK1 | c.345C>A p.N115K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1278496954, COSV65676921; called by muse, mutect2, varscan2
- STX2 | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV55435466; called by muse, mutect2, varscan2
- SUZ12 | c.427A>G p.K143E | Missense Mutation (SNP) | VAF 153/365 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.257); catalogued as COSV59502217; called by muse, mutect2, varscan2
- SV2C | c.1214G>C p.R405T | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV59218668, COSV59225751; called by muse, mutect2, varscan2
- SYNE2 | c.18550C>T p.R6184W | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs761998546, COSV59962250; called by muse, mutect2, varscan2
- TAF4B | c.1833-1G>C p.X611_splice | Splice Site (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99300692; called by muse, mutect2
- TMEM35A | c.416C>A p.S139Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV54501204; called by muse, mutect2, varscan2
- TTN | c.8006C>A p.S2669Y (on ENST00000591111; = p.S2623Y on NM_003319.4) | Missense Mutation (SNP) | VAF 43/195 reads (22%) | PolyPhen benign (0.346); catalogued as COSV60238197; called by muse, mutect2, varscan2
- TTN | c.7060C>T p.R2354C (on ENST00000591111; = p.R2308C on NM_003319.4) | Missense Mutation (SNP) | VAF 34/73 reads (47%) | PolyPhen probably damaging (0.998); catalogued as rs145039979; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- UCP2 | c.337+1G>A p.X113_splice | Splice Site (SNP) | VAF 10/52 reads (19%) | catalogued as rs773260052, COSV60105096; called by muse, mutect2, varscan2
- UNC80 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | catalogued as rs751913925, COSV55890160, COSV55907093; called by muse, mutect2, varscan2
- USH2A | c.10438A>T p.N3480Y | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56410041; called by muse, mutect2, varscan2
- WDR49 | c.577G>A p.A193T (on ENST00000308378 / NM_001366158.1; = p.A534T on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as rs747124354, COSV57713277; called by muse, mutect2, varscan2
- ZFAT | c.2013C>G p.S671R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV64743227; called by muse, mutect2, varscan2
- ZMYM4 | c.1720G>A p.G574S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV58914776; called by muse, mutect2, varscan2
- ZNF429 | c.1595C>T p.T532I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV61914361, COSV61917855; called by mutect2, varscan2
- ZNF778 | c.1981C>T p.H661Y | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV60600679; called by muse, mutect2, varscan2
- MELK | c.1333_1334del p.K445Dfs*4 | Frame Shift Del (DEL) | VAF 36/145 reads (25%) | called by mutect2, pindel, varscan2
- SPANXB1 | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 57/348 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASB2 | c.1248C>T p.G416= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV60111594, COSV60113338; called by muse, mutect2, varscan2
- CAMK2A | c.477G>T p.L159= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV62247167; called by muse, mutect2, varscan2
- CCDC105 | c.105G>A p.L35= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs1192094243, COSV52965015; called by muse, mutect2, varscan2
- CCDC74A | c.612G>A p.A204= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs372926788; called by muse, mutect2, varscan2
- CNTN6 | c.1584C>A p.S528= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs756112961, COSV63183124, COSV63185790; called by mutect2, varscan2
- CUL4A | c.1050G>T p.A350= (on ENST00000375440 / NM_001008895.4; = p.A250= on NM_003589.3) | Silent (SNP) | VAF 69/184 reads (38%) | catalogued as rs771623025, COSV100417449; called by muse, mutect2, varscan2
- GBF1 | c.2937C>T p.I979= (on ENST00000369983 / NM_001377137.1; = p.I978= on NM_004193.3) | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV64147581; called by muse, mutect2, varscan2
- GRM5 | c.21G>T p.L7= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV59609187; called by muse, mutect2, varscan2
- HNRNPD | c.936C>T p.Y312= (on ENST00000313899 / NM_031370.3; = p.Y293= on NM_031369.2) | Silent (SNP) | VAF 43/158 reads (27%) | catalogued as COSV58314471; called by muse, mutect2, varscan2
- HTR3B | c.718C>T p.L240= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV52742488, COSV52746622; called by muse, mutect2, varscan2
- HUS1B | c.522C>T p.N174= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs778700723, COSV57869703; called by muse, mutect2, varscan2
- IGHV1-18 | c.243G>A p.Q81= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as rs782786793; called by muse, mutect2, varscan2
- KIF1A | c.4503G>A p.S1501= (on ENST00000320389 / NM_001379639.1; = p.S1493= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as COSV57496782; called by muse, mutect2, varscan2
- KMO | c.465C>T p.P155= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV100844820, COSV63809876; called by muse, mutect2, varscan2
- KSR2 | c.1746G>A p.P582= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as rs746838223, COSV56687038; called by muse, mutect2, varscan2
- LMNTD1 | c.270G>A p.P90= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs1248724177, COSV51449392; called by muse, mutect2, varscan2
- MAP1B | c.2793C>T p.A931= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs151211314; called by muse, mutect2, varscan2
- OTUD5 | c.63G>A p.P21= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1362625442, COSV50238022; called by mutect2, varscan2
- PARP1 | c.2919C>T p.T973= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as rs759984608, COSV64691613; called by muse, mutect2, varscan2
- PLXNB2 | c.1893G>T p.V631= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV63783537; called by muse, mutect2
- PSMA3 | c.642C>G p.L214= | Silent (SNP) | VAF 104/218 reads (48%) | catalogued as COSV53616868, COSV53617896; called by muse, mutect2, varscan2
- RYR1 | c.13866C>T p.G4622= | Silent (SNP) | VAF 43/85 reads (51%) | catalogued as rs370369058, COSV62097189; called by muse, mutect2, varscan2
- SDK2 | c.5652G>A p.T1884= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as rs150849724; called by muse, mutect2, varscan2
- SLC22A23 | c.1494C>T p.L498= | Silent (SNP) | VAF 29/48 reads (60%) | catalogued as rs1465121412, COSV66678854; called by muse, mutect2, varscan2
- TCTN1 | c.1149C>T p.V383= (on ENST00000551590 / NM_001173975.3; = p.V369= on NM_024549.6) | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as rs759588884, COSV66542111; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRIM41 | c.186G>A p.E62= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV59321179; called by muse, mutect2, varscan2
- UTP20 | c.1302T>C p.D434= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV55382737; called by muse, mutect2, varscan2
- XK | c.405G>A p.A135= | Silent (SNP) | VAF 37/154 reads (24%) | catalogued as rs368021749, COSV66120633; called by muse, mutect2, varscan2
- TCF7L2 | c.1442+699G>C | Intron (SNP) | VAF 37/81 reads (46%) | catalogued as COSV53345976; called by muse, mutect2, varscan2
